Somatic mutation profile of tumor specimen TARGET-10-PAPZZJ-09A (aliquot TARGET-10-PAPZZJ-09A-01D) from TARGET case TARGET-10-PAPZZJ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (691 days).
Specimen TARGET-10-PAPZZJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e895cda-f767-444d-b0f1-ffb8fccf8b73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPZZJ-10A (Blood Derived Normal), aliquot TARGET-10-PAPZZJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d388dca3-a8a4-4978-9614-de878e0e0813

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, RNA 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs886039121, COSV53976492; ClinVar: uncertain significance; called by muse, mutect2
- PIK3C2B | c.3758G>T p.R1253L | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100916125; called by muse, mutect2
- WDFY3 | c.6875G>T p.R2292L | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV55699676; called by muse, mutect2
- WDR62 | c.1978G>A p.G660R | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568355584, COSV54332878; called by muse, mutect2
- DIAPH2 | c.422A>C p.Q141P | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MVB12A | c.388A>G p.T130A | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2
- TRAJ6 | chr14:22539072 GTGC>TCT | Missense Mutation (DEL) | VAF 12/104 reads (12%) | called by pindel, varscan2*
- ZSCAN5A | c.562A>C p.R188= | Silent (SNP) | VAF 16/59 reads (27%) | called by muse, mutect2, varscan2
- FOLH1B | n.11A>C | RNA (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
